Somatic mutation profile of tumor specimen e45c73a8-da96-4269-a039-d43942 (aliquot e45c73a8-da96-4269-a039-d43942_D6_1) from CPTAC case 11BR056, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 52.8 years (19,284 days).
Specimen e45c73a8-da96-4269-a039-d43942: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 264e0248-01a3-49a7-8bad-9d6281650c4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0c693667-415a-4f86-b2fc-c16973 (Blood Derived Normal), aliquot 0c693667-415a-4f86-b2fc-c16973_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8f991eec-a236-4cc6-8b50-513811b06a23

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 10, Splice Region 2, RNA 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 77/220 reads (35%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 69/272 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.017); catalogued as rs541260451; called by muse, mutect2
- CHL1 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs199732455; called by muse, mutect2, varscan2
- COX6B1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs1451939305, COSV55836955; called by muse, mutect2, varscan2
- DDR1 | c.919C>A p.R307S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.08); catalogued as rs1210359448; called by muse, varscan2
- EGFLAM | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs745814224; called by muse, mutect2, varscan2
- FAM107A | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs758002243; called by muse, mutect2, varscan2
- FRAS1 | c.9155G>A p.R3052Q | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs779370839, COSV53609737; called by muse, mutect2, varscan2
- INTS6L | c.1026C>G p.I342M | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs143371309; called by muse, mutect2, varscan2
- NT5E | c.1160G>A p.C387Y | Missense Mutation (SNP) | VAF 59/245 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs756174710; called by muse, mutect2, varscan2
- PTPRN2 | c.1466C>T p.A489V | Missense Mutation (SNP) | VAF 60/193 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as rs773679570, COSV101235153; called by muse, mutect2, varscan2
- SLC4A3 | c.1910G>A p.R637Q | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs372281357; called by muse, mutect2, varscan2
- SMURF2 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868941342; called by muse, mutect2, varscan2
- TECTA | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 46/235 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV50700445; called by muse, mutect2, varscan2
- BAZ1A | c.3468G>C p.K1156N | Missense Mutation (SNP) | VAF 22/157 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CMTM2 | c.237T>G p.N79K | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DCDC2C | c.536G>C p.G179A | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.626); called by muse, mutect2, varscan2
- DNM1L | c.1203T>A p.G401= | Splice Region (SNP) | VAF 32/172 reads (19%) | called by muse, mutect2, varscan2
- FAM189B | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.813); called by mutect2, varscan2
- GLRX3 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGAD | c.859-6C>A | Splice Region (SNP) | VAF 17/161 reads (11%) | called by muse, mutect2, varscan2
- MRC2 | c.2410C>A p.L804M | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- MRM1 | c.170C>G p.P57R | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAT16 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- NCOA5 | c.601T>C p.S201P | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NEUROD4 | c.602A>T p.N201I | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PCDH15 | c.5168C>T p.P1723L | Missense Mutation (SNP) | VAF 22/301 reads (7%) | SIFT tolerated, low confidence (1); called by muse, mutect2
- RALGPS2 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.242); called by muse, mutect2
- RELN | c.1047G>T p.L349F | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TBX22 | c.1409C>T p.P470L | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TIE1 | c.2503G>C p.E835Q | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- TTN | c.365G>T p.R122I | Missense Mutation (SNP) | VAF 16/134 reads (12%) | PolyPhen benign (0.132); called by muse, mutect2, varscan2
- UMODL1 | c.3296T>C p.V1099A (on ENST00000408910 / NM_001004416.2; = p.V1227A on NM_173568.3) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- VPS13C | c.4013A>C p.K1338T (on ENST00000644861 / NM_020821.3; = p.K1295T on NM_017684.5) | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- ZNF521 | c.2788T>G p.Y930D | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- ASB9 | c.450C>T p.V150= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as rs1346948781, COSV100995393; called by muse, mutect2, varscan2
- CBX6 | c.897C>T p.T299= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1185563096; called by muse, mutect2, varscan2
- DCDC1 | c.3262C>T p.L1088= (on ENST00000597505 / NM_001367979.1; = p.L195= on NM_020869.3) | Silent (SNP) | VAF 235/398 reads (59%) | called by muse, mutect2, varscan2
- FAM237A | c.384G>A p.A128= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs376138541, COSV101405557; called by muse, mutect2, varscan2
- IRX5 | c.417C>G p.P139= | Silent (SNP) | VAF 52/371 reads (14%) | called by muse, mutect2, varscan2
- MPEG1 | c.2002C>T p.L668= | Silent (SNP) | VAF 54/217 reads (25%) | catalogued as COSV99915081; called by muse, mutect2, varscan2
- REM1 | c.417G>A p.E139= | Silent (SNP) | VAF 33/131 reads (25%) | catalogued as rs1328786243; called by muse, mutect2, varscan2
- SEMA5B | c.939C>T p.T313= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as rs372284000; called by muse, mutect2, varscan2
- SHC1 | c.321C>T p.L107= | Silent (SNP) | VAF 30/155 reads (19%) | called by muse, mutect2, varscan2
- TMEM132D | c.1380C>T p.D460= | Silent (SNP) | VAF 23/168 reads (14%) | catalogued as rs12815188; called by muse, mutect2, varscan2
- BRWD3 | c.813+35G>A | Intron (SNP) | VAF 21/100 reads (21%) | called by muse, mutect2, varscan2
- NR1H4 | c.-44del | 5'UTR (DEL) | VAF 28/202 reads (14%) | catalogued as rs1179070617; called by mutect2, varscan2
- REXO1L1P | n.705C>T | RNA (SNP) | VAF 18/942 reads (2%) | catalogued as rs1451557993; called by muse, mutect2
